Somatic mutation profile of tumor specimen TARGET-10-PARRKK-09A (aliquot TARGET-10-PARRKK-09A-01D) from TARGET case TARGET-10-PARRKK, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 8.9 years (3,244 days).
Specimen TARGET-10-PARRKK-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 39aad885-1f8e-4899-9d61-cb1acf84e1bb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARRKK-10A (Blood Derived Normal), aliquot TARGET-10-PARRKK-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1bc8f8bb-52e2-452d-8a40-651d2b8ce651

The open-access MAF lists 23 somatic variants for this specimen: 16 protein-altering or splice-affecting, 4 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 4, Intron 1, 3'UTR 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DUOX2 | c.4094G>T p.G1365V | Missense Mutation (SNP) | VAF 29/49 reads (59%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.866); catalogued as COSV66531447, COSV66532801; called by muse, mutect2, varscan2
- FIG4 | c.2225C>A p.A742E | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.701); catalogued as COSV57788585; called by muse, mutect2, varscan2
- KCNB2 | c.1180G>T p.G394W | Missense Mutation (SNP) | VAF 9/115 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV73049981; called by muse, mutect2
- PCDHAC1 | c.1210G>T p.D404Y | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53856028; called by muse, mutect2, varscan2
- RFX3 | c.249G>T p.Q83H | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as COSV100175824; called by muse, varscan2
- TMEM132B | c.2315C>A p.T772N | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV54766285; called by muse, mutect2
- TYRP1 | c.164G>A p.R55H | Missense Mutation (SNP) | VAF 12/14 reads (86%) | SIFT tolerated (0.12); PolyPhen benign (0.191); catalogued as rs139670838; called by muse, varscan2
- BRINP3 | c.1572G>T p.W524C | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- FN1 | c.4951G>T p.A1651S | Missense Mutation (SNP) | VAF 5/78 reads (6%) | SIFT tolerated (0.73); PolyPhen probably damaging (0.981); called by muse, mutect2
- LEO1 | c.544G>T p.D182Y | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.241); called by muse, mutect2
- MRPL43 | c.574G>T p.A192S | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- P3H4 | c.1299G>T p.E433D | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- PFN2 | c.40G>T p.D14Y | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRIO | c.8069C>A p.P2690Q | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- TULP1 | c.908G>T p.R303L | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT tolerated (0.65); PolyPhen benign (0.078); called by muse, mutect2
- UNC80 | c.6871C>A p.P2291T | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.52); PolyPhen benign (0); called by mutect2, varscan2
- FOXJ1 | c.804C>A p.G268= | Silent (SNP) | VAF 8/22 reads (36%) | called by muse, mutect2, varscan2
- GABRA5 | c.1359G>A p.P453= | Silent (SNP) | VAF 16/40 reads (40%) | catalogued as rs372663352; called by muse, mutect2
- KDM5D | c.1590G>T p.L530= | Silent (SNP) | VAF 3/16 reads (19%) | called by muse, varscan2
- TENT4A | c.1474C>A p.R492= | Silent (SNP) | VAF 6/64 reads (9%) | catalogued as COSV50094803; called by muse, mutect2
- FAM161A | c.1583+740G>T | Intron (SNP) | VAF 4/30 reads (13%) | called by mutect2, varscan2
- GLYCTK | c.*1726_*1727dup | 3'UTR (INS) | VAF 4/38 reads (11%) | catalogued as rs780634197; called by mutect2, varscan2
- ZNF32 | c.-12G>T | 5'UTR (SNP) | VAF 4/25 reads (16%) | called by muse, mutect2, varscan2
